Somatic mutation profile of tumor specimen MBCProject_6109_T1C_WES (aliquot MBCProject_6109_T1C_WES_1) from CMI case MBCProject_6109, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 32.0 years (11,672 days).
Specimen MBCProject_6109_T1C_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0470f1d9-8afd-4292-8b4b-96d78714989c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_6109_SALIVA_2 (Saliva), aliquot MBCProject_6109_SALIVA_2_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bc23a6b-8363-4568-acad-799d624e5560

The open-access MAF lists 137 somatic variants for this specimen: 99 protein-altering or splice-affecting, 25 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 25, Intron 7, RNA 4, Nonsense Mutation 3, Frame Shift Ins 2, Splice Region 2, Splice Site 2, Translation Start Site 1, 3'UTR 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AACS | c.916-6C>T | Splice Region (SNP) | VAF 21/101 reads (21%) | catalogued as COSV55537053; called by muse, mutect2, varscan2
- ACAN | c.2542G>A p.V848M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as rs368584197, COSV61358168; called by muse, mutect2, varscan2
- AKAP3 | c.1376C>T p.T459I | Missense Mutation (SNP) | VAF 46/390 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs1315128634; called by muse, mutect2, varscan2
- ALKBH4 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1313136343; called by muse, mutect2
- APOB | c.10331T>G p.L3444R | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51923922; called by muse, mutect2, varscan2
- ARAP2 | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV58292911; called by muse, mutect2, varscan2
- ARMCX2 | c.1587G>C p.L529F | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57529358; called by muse, mutect2, varscan2
- COL4A2 | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 77/508 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV64627712; called by muse, mutect2, varscan2
- DOCK6 | c.5278C>T p.H1760Y | Missense Mutation (SNP) | VAF 61/419 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs763959344; called by muse, mutect2, varscan2
- DOK3 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57253359; called by muse, mutect2, varscan2
- EMILIN1 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs552677456; called by muse, mutect2, varscan2
- GATA3 | c.1003dup p.D335Gfs*17 | Frame Shift Ins (INS) | VAF 252/1096 reads (23%) | catalogued as COSV60519609; called by mutect2, pindel, varscan2
- HDAC7 | c.1832G>A p.R611Q (on ENST00000427332; = p.R650Q on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as rs539537344; called by muse, mutect2, varscan2
- IGDCC3 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 67/378 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1344408428, COSV99080057; called by muse, mutect2, varscan2
- INVS | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 141/747 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as rs761806481, COSV99318409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK10 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 106/596 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as rs370557951, COSV100069359; called by muse, mutect2, varscan2
- KIDINS220 | c.3386C>T p.T1129M | Missense Mutation (SNP) | VAF 49/370 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs775892620, COSV56750260; called by muse, mutect2, varscan2
- LAS1L | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 58/950 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV56706547; called by muse, mutect2
- MUC17 | c.4894C>G p.L1632V | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100075111; called by muse, mutect2, varscan2
- NFIC | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 19/413 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59411588; called by muse, mutect2
- OR2G3 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 25/264 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773500214, COSV100180809; called by muse, mutect2
- PBRM1 | c.3220A>G p.K1074E (on ENST00000296302 / NM_001366071.2; = p.K1049E on NM_018313.5) | Missense Mutation (SNP) | VAF 93/417 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56261574; called by muse, mutect2, varscan2
- PCCA | c.1746+1G>C p.X582_splice | Splice Site (SNP) | VAF 47/438 reads (11%) | catalogued as CS149405; called by muse, mutect2, varscan2
- PLXNC1 | c.1739C>A p.S580Y | Missense Mutation (SNP) | VAF 74/624 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs1285465118; called by muse, varscan2
- PRELID1 | c.513C>T p.G171= | Splice Region (SNP) | VAF 56/750 reads (7%) | catalogued as rs374141318; called by muse, mutect2
- PRKAR1B | c.782A>T p.K261M | Missense Mutation (SNP) | VAF 58/323 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs780449319; called by muse, mutect2, varscan2
- PRKD2 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV52190305; called by muse, mutect2, varscan2
- PTPRD | c.463C>G p.P155A | Missense Mutation (SNP) | VAF 92/632 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV61989323; called by muse, mutect2, varscan2
- SEMA6B | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.065); catalogued as rs755696579, COSV56704146; called by muse, mutect2, varscan2
- SKOR2 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as rs1568091596; called by muse, mutect2, varscan2
- SLC3A1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 85/444 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs1332579288, COSV53221877; called by muse, mutect2, varscan2
- SPDYE4 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1463425414, COSV104409726; called by muse, mutect2, varscan2
- SPTBN4 | c.6115C>T p.R2039C | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs577000571; called by muse, mutect2, varscan2
- STOML3 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 181/567 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1318298606, COSV65511162; called by muse, mutect2, varscan2
- SVIL | c.5489C>T p.A1830V (on ENST00000355867 / NM_021738.3; = p.A1404V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/820 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as rs955294945, COSV63439412; called by muse, mutect2, varscan2
- THAP3 | c.607C>T p.R203W (on ENST00000054650 / NM_001195753.1; = p.R202W on NM_001195752.1) | Missense Mutation (SNP) | VAF 71/441 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs545814166; called by muse, mutect2, varscan2
- TPSAB1 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.195); catalogued as rs550384428, COSV100127258; called by muse, mutect2, varscan2
- TUT1 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV53468613; called by muse, mutect2, varscan2
- ZBED9 | c.3391G>T p.D1131Y | Missense Mutation (SNP) | VAF 75/389 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV71729783; called by muse, mutect2, varscan2
- ZNF135 | c.1195C>T p.Q399* (on ENST00000313434 / NM_001289401.2; = p.Q411* on NM_003436.4) | Nonsense Mutation (SNP) | VAF 73/393 reads (19%) | catalogued as COSV57881948; called by muse, mutect2, varscan2
- ZNF579 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1236250229; called by muse, mutect2, varscan2
- ZXDB | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as rs768725517; called by muse, mutect2, varscan2
- AC006059.2 | c.1893G>T p.E631D | Missense Mutation (SNP) | VAF 52/405 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.065); called by muse, mutect2
- AFP | c.400G>C p.A134P | Missense Mutation (SNP) | VAF 44/634 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- AGO1 | c.2226T>G p.F742L | Missense Mutation (SNP) | VAF 60/375 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APC | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ATP2B4 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); called by muse, mutect2
- C12orf29 | c.354G>A p.W118* | Nonsense Mutation (SNP) | VAF 64/471 reads (14%) | called by muse, mutect2, varscan2
- CACNA1B | c.5050G>T p.A1684S | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CADM2 | c.1242T>A p.D414E (on ENST00000407528 / NM_001167674.2; = p.D416E on NM_153184.4) | Missense Mutation (SNP) | VAF 66/786 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CCDC121 | c.735G>C p.Q245H | Missense Mutation (SNP) | VAF 48/312 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- COG2 | c.1346A>T p.Q449L | Missense Mutation (SNP) | VAF 74/453 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- DGKD | c.1323G>C p.K441N (on ENST00000264057 / NM_152879.3; = p.K397N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DNAJC17 | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 85/401 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- DNAJC17 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 84/397 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ELFN1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM135A | c.3865C>A p.Q1289K (on ENST00000370479 / NM_001351599.1; = p.Q1076K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/342 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FGFBP2 | c.236_237dup p.M80Afs*21 | Frame Shift Ins (INS) | VAF 6/31 reads (19%) | called by mutect2, pindel
- GPNMB | c.1205T>G p.V402G (on ENST00000381990 / NM_001005340.2; = p.V390G on NM_002510.3) | Missense Mutation (SNP) | VAF 74/428 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HRH3 | c.92C>A p.A31E | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.055); called by muse, varscan2
- KLKB1 | c.1653A>T p.R551S | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LAMA2 | c.3992A>G p.D1331G | Missense Mutation (SNP) | VAF 57/362 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); called by muse, varscan2
- LMX1B | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- LYVE1 | c.142G>C p.A48P | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.46); called by muse, mutect2
- LZIC | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAGEA10 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAML1 | c.2498G>A p.G833E | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- METTL15 | c.569G>A p.G190D | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTMR4 | c.2817_2820del p.K940Rfs*19 | Frame Shift Del (DEL) | VAF 156/1132 reads (14%) | called by mutect2, pindel, varscan2
- NKTR | c.933G>C p.K311N | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NUP210L | c.3466G>A p.V1156I | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NXNL2 | c.466G>T p.V156F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5A1 | c.929G>T p.R310M | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- PDCD6IP | c.38C>G p.S13* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2, varscan2
- PRTG | c.1917G>T p.Q639H | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RANBP17 | c.1729G>C p.E577Q | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2
- RAP1GAP | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 11/275 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.389); called by muse, mutect2
- RPS6KA3 | c.1474G>T p.V492L | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SCCPDH | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 46/408 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDK1 | c.1105A>C p.S369R | Missense Mutation (SNP) | VAF 82/561 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SEC16B | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- SETDB1 | c.1679C>G p.A560G | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC26A7 | c.695T>A p.L232H | Missense Mutation (SNP) | VAF 98/408 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC35F3 | c.142G>A p.G48S (on ENST00000366617 / NM_001300845.1; = p.G117S on NM_173508.4) | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOGA3 | c.2670C>A p.D890E | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SPTA1 | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 121/969 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- TBX2 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 22/598 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); called by muse, mutect2
- TDO2 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEAD1 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 71/443 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGFB3 | c.1015T>C p.Y339H | Missense Mutation (SNP) | VAF 77/560 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAV13-1 | c.167A>T p.K56M | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TSC22D2 | c.2257G>A p.G753S | Missense Mutation (SNP) | VAF 18/609 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0.428); called by muse, mutect2
- TSTD2 | c.1253-11_1253-1del p.X418_splice | Splice Site (DEL) | VAF 8/71 reads (11%) | called by mutect2, pindel
- ZBTB7B | c.1297C>T p.H433Y (on ENST00000292176; = p.H467Y on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/440 reads (15%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ZNF281 | c.1019G>C p.S340T | Missense Mutation (SNP) | VAF 30/574 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2
- ZNF354A | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 59/502 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF521 | c.1098C>A p.D366E | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF831 | c.2307A>C p.K769N | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2
- ZNHIT2 | c.641A>G p.Q214R | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- B4GAT1 | c.819C>T p.N273= | Silent (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2, varscan2
- BAG6 | c.2322C>T p.L774= (on ENST00000676571; = p.L727= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as rs1448011022; called by muse, mutect2, varscan2
- CAMSAP1 | c.213G>A p.Q71= | Silent (SNP) | VAF 26/418 reads (6%) | called by muse, mutect2
- CKAP4 | c.1416G>A p.V472= | Silent (SNP) | VAF 45/90 reads (50%) | called by muse, mutect2, varscan2
- EPHA10 | c.2014C>T p.L672= | Silent (SNP) | VAF 33/136 reads (24%) | called by muse, mutect2, varscan2
- ESX1 | c.180C>T p.N60= | Silent (SNP) | VAF 57/383 reads (15%) | catalogued as COSV65424182; called by muse, mutect2, varscan2
- FFAR1 | c.360G>A p.P120= | Silent (SNP) | VAF 32/202 reads (16%) | catalogued as COSV50054796; called by muse, mutect2, varscan2
- GPR162 | c.258C>T p.N86= | Silent (SNP) | VAF 47/406 reads (12%) | catalogued as rs1377735189, COSV50592391; called by muse, mutect2, varscan2
- IL1RAP | c.240G>A p.E80= | Silent (SNP) | VAF 122/750 reads (16%) | called by muse, mutect2, varscan2
- LRRC63 | c.435G>A p.R145= | Silent (SNP) | VAF 37/281 reads (13%) | called by muse, mutect2, varscan2
- NTN5 | c.1179C>T p.A393= | Silent (SNP) | VAF 16/165 reads (10%) | catalogued as rs1310298271; called by muse, mutect2, varscan2
- PHIP | c.3561C>G p.P1187= | Silent (SNP) | VAF 29/358 reads (8%) | catalogued as COSV51501339; called by muse, mutect2
- PRMT9 | c.6G>T p.S2= | Silent (SNP) | VAF 86/628 reads (14%) | catalogued as COSV59361059; called by muse, mutect2, varscan2
- PTGDR2 | c.867C>T p.V289= | Silent (SNP) | VAF 31/203 reads (15%) | called by muse, mutect2, varscan2
- SELENON | c.576A>G p.T192= | Silent (SNP) | VAF 39/171 reads (23%) | called by muse, mutect2, varscan2
- SLC25A14 | c.807C>T p.I269= | Silent (SNP) | VAF 66/437 reads (15%) | catalogued as rs376247628, COSV54417352; called by muse, mutect2, varscan2
- SLC46A1 | c.310C>T p.L104= | Silent (SNP) | VAF 102/1395 reads (7%) | catalogued as rs1417608734; called by muse, mutect2
- SLC46A1 | c.309G>T p.L103= | Silent (SNP) | VAF 102/1402 reads (7%) | called by muse, mutect2
- ST18 | c.2697T>A p.V899= | Silent (SNP) | VAF 62/536 reads (12%) | called by muse, mutect2, varscan2
- TBC1D4 | c.1317G>A p.T439= | Silent (SNP) | VAF 111/728 reads (15%) | catalogued as rs1262636724; called by muse, mutect2, varscan2
- TRAK1 | c.2112G>A p.L704= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as rs528706359; called by muse, mutect2, varscan2
- VCAN | c.2976A>T p.S992= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV54101787; called by muse, mutect2, varscan2
- VKORC1 | c.75C>T p.Y25= | Silent (SNP) | VAF 54/252 reads (21%) | catalogued as rs1246831196; called by muse, mutect2, varscan2
- YME1L1 | c.993C>A p.V331= (on ENST00000326799 / NM_139312.3; = p.V274= on NM_014263.4) | Silent (SNP) | VAF 72/225 reads (32%) | catalogued as rs538552104; called by muse, mutect2, varscan2
- ZFHX2 | c.4434C>T p.D1478= | Silent (SNP) | VAF 33/166 reads (20%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.151+25430C>T | Intron (SNP) | VAF 103/513 reads (20%) | catalogued as rs879110606; called by muse, mutect2, varscan2
- DNPH1 | c.196+92C>T | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- EPB41L1 | c.1669-2249A>C | Intron (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- FAM205BP | n.1165G>A | RNA (SNP) | VAF 57/488 reads (12%) | called by muse, mutect2, varscan2
- FUNDC2P2 | n.380C>A | RNA (SNP) | VAF 118/709 reads (17%) | catalogued as rs1051855176; called by muse, mutect2, varscan2
- GOLGA6L10 | c.*26_*27insC | 3'UTR (INS) | VAF 96/920 reads (10%) | called by mutect2, pindel
- IQSEC1 | c.2847+1494G>C | Intron (SNP) | VAF 30/179 reads (17%) | called by muse, mutect2, varscan2
- LINC01299 | n.2171T>C | RNA (SNP) | VAF 139/960 reads (14%) | called by muse, mutect2, varscan2
- MED12 | c.2542-10C>A | Intron (SNP) | VAF 82/536 reads (15%) | called by muse, mutect2, varscan2
- NBPF7 | n.577G>C | RNA (SNP) | VAF 42/275 reads (15%) | called by muse, mutect2, varscan2
- RIMS2 | c.2084-912C>T | Intron (SNP) | VAF 38/342 reads (11%) | catalogued as rs1392441060, COSV51692040; called by muse, mutect2, varscan2
- UNC93B1 | c.238+9C>G | Intron (SNP) | VAF 28/163 reads (17%) | catalogued as rs1054185641; called by muse, mutect2, varscan2
- ZNF843 | chr16:31434958 T>C | 3'Flank (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2
